Somatic mutation profile of tumor specimen TARGET-10-PANVXF-09A (aliquot TARGET-10-PANVXF-09A-01D) from TARGET case TARGET-10-PANVXF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,507 days).
Specimen TARGET-10-PANVXF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3ae57ab-2830-4dc1-85fc-0b75772764c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVXF-14A (Bone Marrow Normal), aliquot TARGET-10-PANVXF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1eefe248-f5f4-407c-affc-77fa78a58d14

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.2768C>T p.P923L | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV51422992; called by muse, mutect2, varscan2
- RYR1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs890373465, COSV100615230, COSV62102337; ClinVar: uncertain significance; called by muse, mutect2
- TOR3A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs370170124; called by muse, mutect2, varscan2
- HEPH | c.458A>G p.D153G (on ENST00000343002; = p.D207G on NM_138737.5) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IKZF3 | c.240_247del p.E81* | Frame Shift Del (DEL) | VAF 23/85 reads (27%) | called by mutect2, pindel, varscan2
- USH2A | c.477A>T p.Q159H | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- COL6A3 | c.108G>A p.A36= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs374055173; called by muse, mutect2, varscan2
- C5orf60 | n.380T>C | RNA (SNP) | VAF 4/32 reads (13%) | catalogued as rs199764762; called by muse, mutect2
